Somatic mutation profile of tumor specimen TARGET-50-PAJLKC-01A (aliquot TARGET-50-PAJLKC-01A-01D) from TARGET case TARGET-50-PAJLKC, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 6.7 years (2,464 days).
Specimen TARGET-50-PAJLKC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c8d274d-9da0-44bc-b3c4-e221c63a4263.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJLKC-10A (Blood Derived Normal), aliquot TARGET-50-PAJLKC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/177b34b0-9914-4879-8dc2-a8ac7ac1ca00

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGT | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs774320928; called by muse, mutect2, varscan2
- DACT1 | c.2215G>A p.V739M | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as COSV60019466; called by muse, mutect2, varscan2
- ECHS1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as COSV100881916; called by muse, mutect2
- FAM184B | c.2689C>A p.P897T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.127); catalogued as COSV99401872; called by muse, mutect2
- LAMA5 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs373397574; called by muse, mutect2, varscan2
- NCKAP5L | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761693600; called by muse, mutect2, varscan2
- TMEM104 | c.45+2dup p.X15_splice | Splice Site (INS) | VAF 35/83 reads (42%) | catalogued as rs1567856076; called by mutect2, pindel, varscan2
- TNRC18 | c.3273C>A p.Y1091* | Nonsense Mutation (SNP) | VAF 14/14 reads (100%) | catalogued as COSV68163061, COSV68168466; called by muse, mutect2, varscan2
- WDR90 | c.3787G>A p.G1263S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs760357301, COSV53476262; called by muse, mutect2, varscan2
- ZC3H18 | c.2215G>A p.V739M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV56322734; called by muse, mutect2, varscan2
- ZNF814 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.429); catalogued as rs1331219074; called by muse, mutect2, varscan2
- AKAP8 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.861); called by muse, mutect2
- MAST2 | c.2909C>G p.S970C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.535); called by muse, mutect2
- SRRM5 | c.127T>C p.S43P | Missense Mutation (SNP) | VAF 74/131 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TLL1 | c.1238A>C p.Y413S | Missense Mutation (SNP) | VAF 5/118 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2
- FAM161B | c.294C>T p.S98= (on ENST00000651776; = p.S35= on NM_152445.3) | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as rs151173835; called by muse, mutect2, varscan2
- RAI1 | c.843G>A p.Q281= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs748280748, COSV55388680, COSV55398332; called by muse, varscan2
- TM9SF4 | c.1017G>A p.Q339= | Silent (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- RGS11 | c.319-16C>T | Intron (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
